Somatic mutation profile of tumor specimen ALCH-B2NQ-TTP1-A (aliquot ALCH-B2NQ-TTP1-A-2-0-D-A77Z-36) from ALCHEMIST case ALCH-B2NQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.6 years (18,487 days).
Specimen ALCH-B2NQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a772501d-7830-40b5-9180-448df60d5a38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2NQ-NB1-A (Blood Derived Normal), aliquot ALCH-B2NQ-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47477855-0b68-4071-882d-449551f6bfbf

The open-access MAF lists 451 somatic variants for this specimen: 299 protein-altering or splice-affecting, 95 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 95, Nonsense Mutation 26, Intron 21, RNA 14, 3'UTR 12, 5'UTR 7, Splice Site 4, Splice Region 3, 3'Flank 2, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 24/296 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA12 | c.4135C>A p.P1379T (on ENST00000272895 / NM_173076.3; = p.P1061T on NM_015657.3) | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.663); catalogued as COSV55970316; called by muse, mutect2
- ABCB1 | c.696G>T p.W232C | Missense Mutation (SNP) | VAF 19/435 reads (4%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.985); catalogued as COSV55957404; called by muse, mutect2
- ABCB4 | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV55934881; called by muse, mutect2
- ACTL6B | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); catalogued as COSV99355475, COSV99355708; called by muse, mutect2
- ACVRL1 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 24/350 reads (7%) | catalogued as CM111529; called by muse, mutect2
- ALPI | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55014631, COSV99785985; called by muse, mutect2
- AMER2 | c.483C>A p.H161Q | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV63440121; called by muse, mutect2
- ANK2 | c.5264C>A p.S1755Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52145274; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.862); catalogued as rs770011324, COSV51839754; called by mutect2, varscan2
- ANXA7 | c.1345-1G>T p.X449_splice (on ENST00000372919 / NM_001320880.2; = p.X427_splice on NM_001156.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 9/92 reads (10%) | catalogued as COSV65823129; called by muse, mutect2
- ARFIP2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.041); catalogued as rs763245918, COSV54446228; called by muse, mutect2
- ASAP2 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.301); catalogued as rs1429288882, COSV55631195; called by muse, mutect2
- ASTN1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56087548; called by muse, mutect2
- BCORL1 | c.3089G>T p.R1030M | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV99499456; called by muse, mutect2
- BRINP3 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758959582; called by muse, mutect2
- BTNL3 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100732168; called by muse, mutect2, varscan2
- CASP3 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1006886327; called by muse, mutect2
- CCDC144A | c.3178C>A p.H1060N | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs1478577216, COSV60701051; called by muse, mutect2
- COL19A1 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs780786675; called by muse, mutect2
- COL4A2 | c.3142C>A p.P1048T | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV100847275; called by muse, mutect2
- CYP11A1 | c.363C>A p.F121L | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV51435198; called by muse, mutect2
- CYP4B1 | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99596910; called by muse, mutect2
- DEPDC5 | c.2600G>A p.R867H (on ENST00000400246; = p.R936H on NM_014662.5) | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772897391, COSV56692710; called by muse, mutect2
- DNAH3 | c.5360G>C p.R1787P | Missense Mutation (SNP) | VAF 35/440 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs141137569, COSV54524687; called by muse, mutect2
- DNAJB13 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.677); catalogued as rs146910386; called by muse, mutect2, varscan2
- EBF1 | c.1421C>A p.T474N | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); catalogued as COSV58176685; called by muse, mutect2, varscan2
- EDA2R | c.617A>T p.E206V | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV53630247; called by muse, mutect2
- EPHA6 | c.2513G>T p.G838V (on ENST00000389672 / NM_001080448.3; = p.G230V on NM_173655.4) | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as rs893324942; called by muse, mutect2
- EVX2 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1296360345; called by muse, mutect2
- FBLIM1 | c.188G>T p.W63L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV60030294; called by muse, mutect2
- FLG | c.1015C>G p.H339D | Missense Mutation (SNP) | VAF 37/421 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV64243126; called by muse, mutect2
- FLNC | c.5735G>A p.G1912D | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100368432; called by muse, mutect2, varscan2
- GALNT17 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1011047552; called by muse, mutect2
- GATA3 | c.79C>A p.H27N | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV100650976; called by muse, mutect2
- GFOD2 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 20/292 reads (7%) | catalogued as COSV52056753; called by muse, mutect2
- GPR6 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs756140835; called by muse, mutect2
- GUCD1 | c.513dup p.S172Qfs*11 | Frame Shift Ins (INS) | VAF 32/273 reads (12%) | catalogued as rs753347105; called by mutect2, pindel, varscan2
- GZMA | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57113218; called by muse, mutect2
- HAO1 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186791070, COSV101113273; called by muse, mutect2, varscan2
- HDGFL1 | c.138C>A p.H46Q | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100014557; called by muse, mutect2
- HGF | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 25/461 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55947091; called by muse, mutect2
- HIVEP2 | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1202534384; called by muse, mutect2
- KAT14 | c.139T>A p.S47T | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.931); catalogued as rs772493399; called by muse, mutect2
- KCNH7 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59814703; called by muse, mutect2
- LAMC3 | c.4661G>A p.R1554H | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs547090197; called by muse, mutect2
- MDGA2 | c.2718C>A p.F906L (on ENST00000399232 / NM_001113498.2; = p.F608L on NM_182830.4) | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.159); catalogued as COSV62091984; called by muse, mutect2
- MGAM | c.3714G>C p.M1238I | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs1426043027; called by muse, mutect2
- MGAM2 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72176173; called by muse, mutect2
- MMP16 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99689072; called by muse, mutect2
- MMP23B | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1427018209; called by muse, mutect2, varscan2
- MUC12 | c.14417G>T p.G4806V (on ENST00000379442; = p.G4663V on NM_001164462.1) | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious, low confidence (0.01); catalogued as rs1562791424; called by muse, mutect2
- NEB | c.8435G>A p.R2812H | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs772240430, COSV51425086; called by muse, mutect2
- NUP210L | c.5566G>A p.G1856S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.449); catalogued as rs1475803241; called by muse, mutect2
- OCRL | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD991825, COSV99058263; called by muse, mutect2
- OPHN1 | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV100830740; called by muse, mutect2
- OR14C36 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV100507544, COSV58602112; called by muse, mutect2
- OR2M7 | c.74C>G p.T25S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.418); catalogued as COSV58737687; called by muse, mutect2
- OR4C15 | c.51del p.N18Tfs*3 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | catalogued as COSV58953941; called by mutect2, pindel, varscan2
- ORC1 | c.1526A>G p.Q509R | Missense Mutation (SNP) | VAF 39/535 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs942079227; called by muse, mutect2
- PCDHB10 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 29/367 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53383703; called by muse, mutect2
- PHKA1 | c.2420G>T p.R807I | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV59801542; called by muse, mutect2
- PLEKHH2 | c.2104G>T p.E702* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV56749321; called by muse, mutect2
- PRDM9 | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 66/696 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs776657408, COSV57006202, COSV57012672; called by muse, mutect2
- PRODH2 | c.1021G>A p.G341S (on ENST00000301175; = p.G265S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs1202719042; called by muse, mutect2
- PRPF6 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1280305179; called by muse, mutect2
- PZP | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs1385616773; called by muse, mutect2
- RBMXL3 | c.1636C>A p.R546S | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.353); catalogued as rs781978689; called by muse, mutect2
- RBMXL3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.136); catalogued as rs782106608, COSV57752054; called by muse, mutect2, varscan2
- RNASE13 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV58795604; called by muse, mutect2
- RPE65 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs768448761, CM167087, COSV52017060; called by muse, mutect2
- RYR2 | c.3769C>T p.Q1257* | Nonsense Mutation (SNP) | VAF 12/184 reads (7%) | catalogued as COSV63698700; called by muse, mutect2
- RYR3 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV101212384; called by muse, mutect2
- SALL4 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 49/609 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565664808; called by muse, mutect2
- SELP | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV55258324; called by muse, mutect2
- SLC26A5 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181023877, COSV59700903; called by muse, mutect2
- SLC35F6 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733768; called by muse, mutect2
- SLC41A2 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs1407925125; called by muse, mutect2
- SLC5A8 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV73310431, COSV73310608; called by muse, mutect2
- SLITRK2 | c.744G>T p.R248S | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100157253; called by muse, mutect2
- SLITRK6 | c.1946G>T p.R649I | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV68390195; called by muse, mutect2, varscan2
- SPTA1 | c.7228G>T p.V2410F | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63524023; called by muse, mutect2, varscan2
- SRCAP | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199558797, COSV52669034, COSV52681485; called by muse, mutect2
- STAG2 | c.374C>A p.S125* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV54367617, COSV54367654; called by muse, mutect2
- TECTA | c.5059G>A p.G1687S | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as COSV50705285; called by muse, mutect2
- TET1 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1283019815; called by muse, mutect2
- TGIF2LX | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 32/562 reads (6%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.796); catalogued as COSV99383386; called by muse, mutect2
- TMC1 | c.1761C>T p.I587= | Splice Region (SNP) | VAF 34/538 reads (6%) | catalogued as COSV99920454; called by muse, mutect2
- TPTE | c.574C>A p.H192N (on ENST00000618007 / NM_199261.4; = p.H174N on NM_199259.4) | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs1229365937; called by muse, mutect2
- TRPA1 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.36); catalogued as rs201102897; called by muse, mutect2
- TRRAP | c.5231A>T p.Y1744F (on ENST00000359863 / NM_001244580.1; = p.Y1726F on NM_003496.3) | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV100723169; called by muse, mutect2
- TVP23A | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99296686; called by muse, mutect2
- UGT8 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV60420463; called by muse, mutect2, varscan2
- XPNPEP2 | c.1396G>T p.V466F | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100941440; called by muse, mutect2
- ZKSCAN8 | c.1066G>T p.G356C | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1453731905; called by muse, mutect2
- ZNF138 | c.803G>C p.R268T (on ENST00000307355 / NM_001367572.1; = p.R242T on NM_006524.4) | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV56463941; called by muse, mutect2
- ZNF676 | c.187T>A p.W63R (on ENST00000650058; = p.W31R on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV68093931; called by muse, mutect2
- ZP4 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63910757, COSV63912483; called by muse, mutect2
- ZXDA | c.1530C>A p.F510L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62387392; called by muse, mutect2
- AARS2 | c.1097A>T p.K366M | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- AARS2 | c.1096A>T p.K366* | Nonsense Mutation (SNP) | VAF 32/494 reads (6%) | called by muse, mutect2
- ABCB1 | c.695G>A p.W232* | Nonsense Mutation (SNP) | VAF 18/430 reads (4%) | called by muse, mutect2
- ACKR1 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACSL4 | c.1014C>A p.C338* (on ENST00000340800 / NM_022977.2; = p.C297* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/433 reads (7%) | called by muse, mutect2
- ACVR1B | c.922G>C p.A308P | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ADAM32 | c.2293G>T p.D765Y | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- ADCY1 | c.2792G>T p.G931V | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGXT | c.693C>G p.Y231* | Nonsense Mutation (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- AIRE | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDOA | c.486G>T p.K162N (on ENST00000642816 / NM_001243177.4; = p.K108N on NM_184041.5) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AMER1 | c.1537G>C p.D513H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- APPL2 | c.1675_1680del p.E559_L560del | In Frame Del (DEL) | VAF 9/84 reads (11%) | called by mutect2, pindel
- ARFGEF2 | c.3472G>T p.V1158F | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ARHGEF4 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2
- ARMCX4 | c.319C>G p.R107G (on ENST00000433011; = p.R3G on NM_001256155.2) | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ARMCX5-GPRASP2 | c.515A>T p.N172I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ASB17 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); called by muse, mutect2
- ATP1A4 | c.963G>T p.L321F | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATPAF1 | c.707G>T p.S236I (on ENST00000574428; = p.S259I on NM_022745.4) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ATR | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); called by muse, mutect2
- BLM | c.2231C>G p.S744* | Nonsense Mutation (SNP) | VAF 8/232 reads (3%) | called by muse, mutect2
- BRDT | c.2416T>A p.W806R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BTF3 | c.219G>C p.K73N (on ENST00000380591 / NM_001037637.1; = p.K29N on NM_001207.4) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- C10orf71 | c.3911C>T p.T1304M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C18orf63 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.121); called by muse, mutect2
- C2CD3 | c.4865G>T p.R1622L | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- C3AR1 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- CAPRIN1 | c.1248A>T p.R416S | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); called by muse, mutect2
- CCT5 | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CEP85L | c.2417G>T p.*806Lext*29 | Nonstop Mutation (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- CERK | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 23/392 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.104); called by muse, mutect2
- CFAP61 | c.2160C>G p.D720E | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, varscan2
- CHD9 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); called by muse, mutect2
- CLASRP | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.28); called by muse, mutect2
- CLSTN2 | c.1184C>A p.A395D | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNGA2 | c.1966C>A p.P656T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by mutect2, varscan2
- COG1 | c.473A>T p.Q158L | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- COL11A1 | c.2852G>T p.R951L | Missense Mutation (SNP) | VAF 15/347 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- COL2A1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A2 | c.3838G>T p.E1280* | Nonsense Mutation (SNP) | VAF 40/447 reads (9%) | called by muse, mutect2
- COL8A2 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.374); called by muse, mutect2
- COPE | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2
- CPS1 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.3804T>G p.I1268M (on ENST00000297405 / NM_001363185.1; = p.I1164M on NM_052900.3) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- CSTF2 | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2
- CTLA4 | c.544A>C p.T182P | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- CTTNBP2NL | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- DBX2 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); called by muse, mutect2
- DBX2 | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
- DGAT2 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.306); called by muse, mutect2
- DMD | c.9118G>A p.E3040K | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAJA3 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.376); called by muse, mutect2
- DOCK11 | c.4159G>T p.E1387* | Nonsense Mutation (SNP) | VAF 34/346 reads (10%) | called by muse, mutect2, varscan2
- DPP10 | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.165); called by muse, mutect2
- DSG2 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 38/420 reads (9%) | called by muse, mutect2
- DTX3L | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- DUOX1 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- EMX1 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); called by muse, mutect2
- ENPP3 | c.489G>C p.L163F | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- EP300 | c.3742A>T p.T1248S | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- ERBIN | c.4157T>C p.I1386T (on ENST00000284037 / NM_001253697.2; = p.I1345T on NM_018695.4) | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2
- EVX1 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM135B | c.3709C>G p.L1237V | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM184B | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- FAM189A1 | c.1229-1G>T p.X410_splice | Splice Site (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2
- FAP | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FGD1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.134); called by muse, mutect2
- FLG | c.2045C>A p.T682N | Missense Mutation (SNP) | VAF 47/399 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- FLNA | c.4009G>T p.G1337C | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FSIP2 | c.6463A>G p.I2155V | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- FYB1 | c.311A>T p.E104V | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GNAS | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2
- GPRASP1 | c.2774G>T p.C925F | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.276); called by muse, mutect2
- GRIN2D | c.1096A>T p.N366Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HADH | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2
- HDDC2 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 11/160 reads (7%) | called by muse, mutect2
- HERC2 | c.5690A>T p.E1897V | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- HGF | c.2102A>G p.N701S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- HIVEP2 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- HMGCLL1 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- HMGCS1 | c.1066G>C p.V356L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HTATSF1 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- IGHV2-5 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IGKV1D-43 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.176); called by muse, mutect2
- IGSF10 | c.5472C>A p.N1824K | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2
- IL17A | c.119A>T p.N40I | Missense Mutation (SNP) | VAF 48/544 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- IL18RAP | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- INTU | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by mutect2, varscan2
- IQCJ-SCHIP1 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.027); called by muse, mutect2
- IQUB | c.2012A>T p.Q671L | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2
- ITGA11 | c.2477C>G p.T826S | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.077); called by muse, mutect2
- ITGB1BP2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IVL | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAKMIP1 | c.1102-2A>G p.X368_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2
- KANK4 | c.1645G>T p.G549* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- KCNQ2 | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- KIF14 | c.1834A>T p.T612S | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- KIF26B | c.1981A>G p.I661V | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.607); called by muse, mutect2
- KLHL33 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by mutect2, varscan2
- KLHL4 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.007); called by muse, mutect2
- LAMA1 | c.2049C>G p.Y683* | Nonsense Mutation (SNP) | VAF 32/409 reads (8%) | called by muse, mutect2
- LCT | c.3203A>T p.Y1068F | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.158); called by muse, mutect2
- LIFR | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- LIPC | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- LPO | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); called by muse, mutect2
- LRRC1 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.338); called by muse, mutect2
- MAB21L1 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2
- MAGEA1 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 29/412 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- MED12 | c.1820A>G p.D607G | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- MED12 | c.3597C>G p.I1199M | Missense Mutation (SNP) | VAF 19/388 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- MEP1B | c.1895C>A p.S632* | Nonsense Mutation (SNP) | VAF 19/257 reads (7%) | called by muse, mutect2
- MPPED1 | c.839A>T p.H280L | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- MTSS1 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 40/577 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2
- MYH1 | c.1515G>T p.K505N | Missense Mutation (SNP) | VAF 33/576 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYH2 | c.5425C>A p.L1809M | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.384); called by muse, mutect2
- MYPN | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- NEB | c.10738G>T p.G3580W | Missense Mutation (SNP) | VAF 41/616 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- NLGN4X | c.2302C>G p.P768A | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- NLRP1 | c.1670A>T p.Q557L | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2
- NTSR2 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- NUP133 | c.2308G>T p.G770C | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OBSL1 | c.4539A>G p.I1513M | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- OR10G4 | c.719G>C p.C240S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- OR2K2 | c.568A>C p.S190R (on ENST00000374428; = p.S161R on NM_205859.2) | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.259); called by muse, mutect2
- OR51F1 | c.622G>T p.G208* | Nonsense Mutation (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- OR5B2 | c.715T>A p.C239S | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- OR6N1 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR6P1 | c.705C>A p.H235Q | Missense Mutation (SNP) | VAF 48/692 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PAGE2 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- PAK3 | c.364A>G p.I122V (on ENST00000262836 / NM_001324328.2; = p.I107V on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2
- PCLO | c.8399G>T p.C2800F | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2
- PHIP | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- PHKA1 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2
- PIGX | c.612G>C p.W204C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3R6 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- PKD2 | c.2736G>T p.E912D | Missense Mutation (SNP) | VAF 47/532 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2
- PLCE1 | c.2284G>C p.E762Q | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2
- PLXNB3 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- POM121L12 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- PPFIA4 | c.1761G>T p.P587= | Splice Region (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- PPP1R1B | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRRC2A | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- PSME4 | c.2705A>T p.Q902L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PTCHD4 | c.1720G>T p.V574F | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, mutect2
- RELN | c.5481T>A p.N1827K | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.445); called by muse, mutect2
- RFX8 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.024); called by muse, mutect2
- RNF112 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2
- RTL3 | c.805T>A p.Y269N | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- RTL9 | c.2957G>T p.G986V | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RTN3 | c.356A>T p.K119I (on ENST00000377819 / NM_001265589.2; = p.K100I on NM_201428.3) | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- RUVBL1 | c.203T>A p.L68* | Nonsense Mutation (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- RYR1 | c.3095G>C p.R1032P | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2
- RYR1 | c.5413G>T p.E1805* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- SARDH | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SATL1 | c.866G>A p.R289K (on ENST00000395409; = p.R476K on NM_001012980.2) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SCN9A | c.1727G>C p.S576T | Missense Mutation (SNP) | VAF 20/463 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2
- SECTM1 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- SEPHS1 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETBP1 | c.4359G>T p.R1453S | Missense Mutation (SNP) | VAF 22/337 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2
- SGCA | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- SLC36A2 | c.575C>G p.T192R | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); called by muse, mutect2
- SLC5A5 | c.721C>G p.R241G | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLITRK3 | c.1843C>A p.L615M | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2
- SLITRK3 | c.1459T>A p.F487I | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- SNAP25 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOBP | c.1946C>A p.P649Q | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2
- SORCS3 | c.3443+1G>T p.X1148_splice | Splice Site (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- SRSF8 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- STRA6 | c.1300+5G>T | Splice Region (SNP) | VAF 21/419 reads (5%) | called by muse, mutect2
- SVEP1 | c.7782G>C p.Q2594H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYDE2 | c.327G>T p.R109S | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- SYNE1 | c.17609A>T p.N5870I (on ENST00000367255 / NM_182961.4; = p.N5799I on NM_033071.3) | Missense Mutation (SNP) | VAF 50/595 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- TBX22 | c.938C>A p.A313E | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.113); called by muse, mutect2
- TBXT | c.1151C>A p.T384K | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- TCERG1L | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- THSD7A | c.2765G>T p.C922F | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TLR4 | c.1904G>T p.G635V (on ENST00000355622 / NM_138554.5; = p.G595V on NM_003266.4) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- TMEM171 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2
- TNN | c.3317G>T p.G1106V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRO | c.1861C>T p.L621F | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRPC5 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTLL6 | c.1805T>A p.L602H (on ENST00000393382 / NM_001130918.3; = p.L295H on NM_173623.3) | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- TTPA | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TXLNG | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- TXNDC16 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- UBE2NL | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 40/445 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2
- UBTFL1 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- VN1R5 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- WDR35 | c.1199A>T p.E400V | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ZC3H12C | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZC3H4 | c.2488A>T p.S830C | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- ZNF33B | c.95G>T p.S32I | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- ZNF423 | c.2435G>T p.S812I (on ENST00000563137 / NM_001379286.1; = p.S804I on NM_015069.4) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZNF479 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- ZNF525 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF700 | c.1092T>G p.C364W | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNFX1 | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2
- ZRANB3 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- ZSWIM6 | c.2092G>T p.G698W | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB1 | c.882A>T p.T294= | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as COSV99712752; called by muse, mutect2
- ACTG1 | c.507C>T p.Y169= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs1555666765, COSV59511594; called by muse, mutect2, varscan2
- ADAD1 | c.462A>T p.A154= | Silent (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- ADAMTS4 | c.693C>A p.A231= | Silent (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.237C>A p.P79= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1200238932, COSV104429335; called by muse, mutect2
- ADGB | c.1374G>A p.L458= | Silent (SNP) | VAF 13/239 reads (5%) | catalogued as rs1331622809; called by muse, mutect2
- ADGRB3 | c.3738C>A p.S1246= | Silent (SNP) | VAF 17/195 reads (9%) | called by muse, mutect2
- BGN | c.834C>A p.T278= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as rs782224247; called by muse, mutect2
- BNC1 | c.702G>A p.E234= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- C6orf118 | c.492T>C p.P164= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as rs1240060468; called by muse, mutect2
- CACNA1A | c.159G>T p.A53= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as rs767892925, COSV64191122; ClinVar: uncertain significance; called by muse, mutect2
- CALN1 | c.420C>A p.L140= (on ENST00000329008 / NM_001017440.3; = p.L182= on NM_031468.4) | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- CKMT2 | c.901C>A p.R301= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- CLSTN2 | c.1185C>A p.A395= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- CNGB3 | c.76C>A p.R26= | Silent (SNP) | VAF 30/412 reads (7%) | catalogued as COSV60695307; called by muse, mutect2
- CNNM1 | c.912G>T p.S304= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- DGKK | c.1884G>T p.P628= | Silent (SNP) | VAF 9/244 reads (4%) | catalogued as rs374545607, COSV101053190; called by muse, mutect2
- DHRS11 | c.696G>T p.V232= | Silent (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- DNAH9 | c.3402C>G p.L1134= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- DNAI2 | c.1164C>A p.A388= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- DNASE1L3 | c.864C>A p.T288= | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- DOCK2 | c.4938C>A p.I1646= | Silent (SNP) | VAF 23/279 reads (8%) | called by muse, mutect2
- DSC2 | c.9A>T p.A3= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- EIF4G3 | c.2715G>T p.L905= | Silent (SNP) | VAF 20/313 reads (6%) | called by muse, mutect2
- ENPP4 | c.385A>C p.R129= | Silent (SNP) | VAF 33/376 reads (9%) | called by muse, mutect2
- FAM205A | c.2332C>A p.R778= | Silent (SNP) | VAF 36/605 reads (6%) | called by muse, mutect2
- FANCM | c.813T>G p.S271= | Silent (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- FRMPD3 | c.2190G>T p.L730= | Silent (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- FSIP2 | c.8046A>G p.L2682= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as rs1429427809; called by muse, mutect2
- GALNT12 | c.33G>T p.P11= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- GIPR | c.1200G>A p.Q400= | Silent (SNP) | VAF 21/233 reads (9%) | called by muse, mutect2
- GOLGA6L22 | c.1482G>A p.E494= | Silent (SNP) | VAF 24/493 reads (5%) | catalogued as COSV99081872; called by muse, mutect2
- GRM3 | c.600C>A p.A200= | Silent (SNP) | VAF 30/290 reads (10%) | catalogued as COSV64468884, COSV64475319; called by muse, mutect2, varscan2
- HGF | c.1350C>A p.P450= | Silent (SNP) | VAF 26/382 reads (7%) | called by muse, mutect2
- HTR2C | c.216C>A p.I72= | Silent (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- ID2 | c.9C>T p.A3= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs949029751; called by muse, mutect2
- IQCB1 | c.1296G>C p.A432= | Silent (SNP) | VAF 30/298 reads (10%) | catalogued as COSV100181514; called by muse, mutect2, varscan2
- IQSEC3 | c.2337C>T p.I779= (on ENST00000538872 / NM_001170738.2; = p.I476= on NM_015232.1) | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as COSV58280385; called by muse, mutect2
- KCNQ2 | c.1740C>T p.S580= (on ENST00000359125 / NM_172107.4; = p.S552= on NM_004518.6) | Silent (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- KIAA1549L | c.642A>T p.T214= (on ENST00000321505; = p.T511= on NM_012194.3) | Silent (SNP) | VAF 14/189 reads (7%) | called by muse, mutect2
- KIF1A | c.3876C>T p.T1292= (on ENST00000320389 / NM_001379639.1; = p.T1284= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- KIF4A | c.2583G>T p.L861= | Silent (SNP) | VAF 20/424 reads (5%) | called by muse, mutect2
- KL | c.660G>A p.A220= | Silent (SNP) | VAF 36/388 reads (9%) | catalogued as rs767353726; called by muse, mutect2
- LIMD2 | c.342C>T p.L114= | Silent (SNP) | VAF 15/183 reads (8%) | called by muse, mutect2
- LRP2 | c.5334G>A p.Q1778= | Silent (SNP) | VAF 13/189 reads (7%) | called by muse, mutect2
- LRRC26 | c.360G>A p.A120= | Silent (SNP) | VAF 54/290 reads (19%) | called by muse, mutect2, varscan2
- LRRC40 | c.301C>T p.L101= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- MAF | c.1128G>A p.R376= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as rs1026368264; called by muse, mutect2
- MAGEA6 | c.738C>G p.L246= | Silent (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- MCM10 | c.1641G>T p.G547= (on ENST00000484800 / NM_182751.3; = p.G546= on NM_018518.5) | Silent (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2
- MROH9 | c.183T>A p.S61= | Silent (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- NFASC | c.3054G>T p.V1018= | Silent (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- NGF | c.192G>T p.A64= | Silent (SNP) | VAF 24/310 reads (8%) | called by muse, mutect2
- NNMT | c.198C>A p.P66= | Silent (SNP) | VAF 40/451 reads (9%) | catalogued as COSV100248872; called by muse, mutect2
- NR2F1 | c.852C>A p.A284= | Silent (SNP) | VAF 30/279 reads (11%) | catalogued as COSV59067695; called by muse, mutect2, varscan2
- NRXN1 | c.3753C>T p.T1251= | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- NUP88 | c.1893A>G p.E631= | Silent (SNP) | VAF 12/316 reads (4%) | catalogued as rs1343118033; called by muse, mutect2
- OR4D11 | c.507T>C p.C169= | Silent (SNP) | VAF 18/323 reads (6%) | called by muse, mutect2
- OR6N1 | c.348A>G p.T116= | Silent (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- OR9A4 | c.672C>G p.T224= | Silent (SNP) | VAF 17/197 reads (9%) | catalogued as COSV71885822; called by muse, mutect2
- PCLO | c.8400C>T p.C2800= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- PKP4 | c.1647G>T p.A549= | Silent (SNP) | VAF 26/494 reads (5%) | catalogued as rs200556653; called by muse, mutect2
- PRKX | c.198G>T p.V66= | Silent (SNP) | VAF 26/376 reads (7%) | called by muse, mutect2
- PRUNE2 | c.4095G>T p.L1365= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- PSG2 | c.897T>C p.Y299= | Silent (SNP) | VAF 28/385 reads (7%) | catalogued as rs376170050; called by muse, mutect2
- PTBP1 | c.522G>T p.G174= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs769826830; called by muse, mutect2
- RBM15B | c.444C>G p.P148= | Silent (SNP) | VAF 44/379 reads (12%) | called by muse, mutect2, varscan2
- RGS2 | c.471G>T p.L157= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- RIMBP2 | c.1431G>T p.V477= | Silent (SNP) | VAF 8/63 reads (13%) | called by mutect2, varscan2
- ROBO4 | c.663C>A p.A221= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- RPGRIP1 | c.1914A>G p.T638= | Silent (SNP) | VAF 25/272 reads (9%) | called by muse, mutect2
- SEPTIN9 | c.975G>T p.R325= (on ENST00000427177 / NM_001113491.2; = p.R307= on NM_006640.4) | Silent (SNP) | VAF 26/353 reads (7%) | called by muse, mutect2
- SLA2 | c.678T>C p.F226= | Silent (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- SLC25A43 | c.654C>T p.L218= | Silent (SNP) | VAF 13/223 reads (6%) | called by muse, mutect2
- SLC5A10 | c.1449G>T p.G483= (on ENST00000395645 / NM_001042450.4; = p.G499= on NM_152351.5) | Silent (SNP) | VAF 17/220 reads (8%) | called by muse, mutect2
- SLC6A17 | c.1017C>T p.I339= | Silent (SNP) | VAF 17/207 reads (8%) | catalogued as COSV58996635; called by muse, mutect2
- SLIT3 | c.2346G>A p.L782= | Silent (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- SPAM1 | c.1464A>T p.T488= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- SPEG | c.240G>T p.G80= | Silent (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- TCIRG1 | c.1935C>T p.P645= | Silent (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- TIAM2 | c.948C>A p.I316= | Silent (SNP) | VAF 19/240 reads (8%) | called by muse, mutect2
- TLE2 | c.1563C>T p.G521= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV53583993; called by mutect2, varscan2
- TMEM132B | c.3093C>T p.T1031= | Silent (SNP) | VAF 39/396 reads (10%) | called by muse, mutect2
- TNR | c.3417C>A p.A1139= | Silent (SNP) | VAF 23/268 reads (9%) | called by muse, mutect2
- TRAV21 | c.96C>A p.V32= | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2
- TRBV28 | c.9C>A p.I3= | Silent (SNP) | VAF 20/209 reads (10%) | called by muse, mutect2
- TROAP | c.1566C>T p.P522= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV99226894; called by muse, varscan2
- TYR | c.435C>A p.I145= | Silent (SNP) | VAF 32/442 reads (7%) | called by muse, mutect2
- UBN1 | c.1278C>G p.L426= | Silent (SNP) | VAF 20/295 reads (7%) | called by muse, mutect2
- ZFPM2 | c.1422C>A p.P474= | Silent (SNP) | VAF 45/676 reads (7%) | called by muse, mutect2
- ZNF365 | c.705C>T p.R235= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- ZNF492 | c.321T>G p.T107= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- ZNF492 | c.408T>A p.T136= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- ZNF711 | c.2268C>T p.H756= | Silent (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2
- ZNF746 | c.486C>T p.P162= | Silent (SNP) | VAF 25/251 reads (10%) | catalogued as rs749384217; called by muse, mutect2
- ABCA4 | c.2918+1040A>T | Intron (SNP) | VAF 35/512 reads (7%) | called by muse, mutect2
- AC006305.1 | n.1152G>T | RNA (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- AC006305.1 | n.738C>A | RNA (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- AC006486.1 | c.23-3008C>A | Intron (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- AC073348.1 | n.6G>T | RNA (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- AC132807.2 | n.110G>T | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- ACTG1P17 | n.660G>A | RNA (SNP) | VAF 11/127 reads (9%) | catalogued as rs914973544; called by muse, mutect2
- AGPAT3 | c.-48-4435G>T | Intron (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
- AHCYL1 | c.120+19del | Intron (DEL) | VAF 9/82 reads (11%) | called by mutect2, pindel
- ALDH3A2 | c.*45C>G | 3'UTR (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- AMPH | c.1182+291G>C | Intron (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2
- ARHGAP17 | c.1491-31G>T | Intron (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- ARMCX4 | c.1039-3831G>T | Intron (SNP) | VAF 11/226 reads (5%) | called by muse, mutect2
- ARPP19P2 | n.127C>A | RNA (SNP) | VAF 12/312 reads (4%) | catalogued as rs1410606569; called by muse, mutect2
- BABAM2 | c.1089-11140G>T | Intron (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- BTN2A3P | n.874G>T | RNA (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2
- C22orf34 | n.165G>C | RNA (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- CAGE1 | chr6:7326791 C>A | 3'Flank (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- CELA2A | c.*39G>T | 3'UTR (SNP) | VAF 16/211 reads (8%) | called by muse, mutect2
- CELSR1 | c.7760-131G>A | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2734G>C | 3'UTR (SNP) | VAF 32/512 reads (6%) | called by muse, mutect2
- CNTNAP2 | c.1499-17523C>A | Intron (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- COL1A2 | c.3105+22C>A | Intron (SNP) | VAF 34/438 reads (8%) | catalogued as COSV51964303; called by muse, mutect2
- CXCR2P1 | n.762A>T | RNA (SNP) | VAF 22/212 reads (10%) | called by muse, mutect2, varscan2
- CYBRD1 | c.*44A>G | 3'UTR (SNP) | VAF 17/194 reads (9%) | called by muse, mutect2
- DDX41 | c.*275G>T | 3'UTR (SNP) | VAF 13/185 reads (7%) | called by muse, mutect2
- DPP6 | c.627+20881G>C | Intron (SNP) | VAF 47/430 reads (11%) | called by muse, mutect2, varscan2
- DPP6 | c.*221C>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as rs1263215517; called by mutect2, varscan2
- EPB41L4A | chr5:112161530 T>G | 3'Flank (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- FAM90A20P | n.918G>C | RNA (SNP) | VAF 20/329 reads (6%) | called by muse, mutect2
- FCRL5 | c.307+710T>A | Intron (SNP) | VAF 23/197 reads (12%) | called by muse, mutect2, varscan2
- FKBP10 | c.*25G>A | 3'UTR (SNP) | VAF 13/244 reads (5%) | catalogued as rs1555617419; called by muse, mutect2
- FMR1 | c.*1298G>T | 3'UTR (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- GABRG2 | c.-1G>A | 5'UTR (SNP) | VAF 60/535 reads (11%) | catalogued as rs780572044, COSV100729682; called by muse, mutect2, varscan2
- GDAP1 | c.*2449A>T | 3'UTR (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- H2BC18 | c.378-9712C>T | Intron (SNP) | VAF 11/195 reads (6%) | catalogued as rs1553752278; called by muse, mutect2
- HACD1 | c.257+1357C>T | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- HEPACAM | c.-8C>A | 5'UTR (SNP) | VAF 17/295 reads (6%) | called by muse, mutect2
- LMF1 | c.*437A>G | 3'UTR (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- MED6 | c.-7C>T | 5'UTR (SNP) | VAF 19/213 reads (9%) | catalogued as rs374165391; called by muse, mutect2
- MID2 | c.-66G>T | 5'UTR (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- MRPL52 | chr14:22829860 del GTGGCCACCGAGGCCACGCCT | 5'Flank (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- NAGLU | c.*47A>G | 3'UTR (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- NOC2LP2 | n.698T>C | RNA (SNP) | VAF 17/222 reads (8%) | called by muse, mutect2
- NPIPB1P | n.202C>A | RNA (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2, varscan2
- OR2L1P | n.512G>A | RNA (SNP) | VAF 24/385 reads (6%) | called by muse, mutect2
- PHF24 | c.-1C>A | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- POLR2J3 | c.*54+320C>A | Intron (SNP) | VAF 29/385 reads (8%) | called by muse, mutect2
- RGS21 | c.-31G>T | 5'UTR (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- SCMH1 | c.-3G>A | 5'UTR (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
- SLC13A1 | c.661-2202C>A | Intron (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- SPAG16 | c.942+47059C>G | Intron (SNP) | VAF 10/120 reads (8%) | catalogued as rs1559116849; called by muse, mutect2
- TMPRSS11F | c.1015+2103G>A | Intron (SNP) | VAF 36/333 reads (11%) | catalogued as COSV62466856; called by muse, mutect2, varscan2
- TRDN | c.793+52A>G | Intron (SNP) | VAF 7/138 reads (5%) | catalogued as COSV62116482; called by muse, mutect2
- ULK1 | c.247-32G>T | Intron (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- ZNF300P1 | n.1291G>T | RNA (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2
- ZNF99 | c.*3021C>A | 3'UTR (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
